Somatic mutation profile of tumor specimen TCGA-YU-AA61-01A (aliquot TCGA-YU-AA61-01A-11D-A435-10) from TCGA case TCGA-YU-AA61, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 29.1 years (10,635 days).
Specimen TCGA-YU-AA61-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c89946c0-2b31-49c7-b039-653d5e58afa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-AA61-10A (Blood Derived Normal), aliquot TCGA-YU-AA61-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1af16cef-96ad-4102-ab83-2025765a8ca6

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLTC | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1409580657, COSV52246044; called by muse, mutect2, varscan2
- KIF1B | c.3008G>A p.R1003Q (on ENST00000377086 / NM_001365952.1; = p.R957Q on NM_015074.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs755104684; called by muse, mutect2, varscan2
- SCAF1 | c.166+1G>A p.X56_splice | Splice Site (SNP) | VAF 29/153 reads (19%) | catalogued as COSV62182965; called by muse, mutect2, varscan2
- SCAPER | c.3743G>T p.R1248L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57748985; called by muse, mutect2
- BIRC6 | c.4196G>T p.S1399I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2
- CKAP5 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- DSE | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- GABRA1 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC5 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- PGBD2 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGR | c.2036A>T p.Q679L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SYTL4 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- EXOSC1 | c.105G>A p.S35= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV61749749; called by muse, mutect2, varscan2
- KIFBP | c.474A>C p.A158= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
